Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4469, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4469-01A (Primary Tumor).

■

Diagnosis:

Total gastrectomy preparation with inclusion of an extensive, partially ulcerated, poorly differentiated adenocarcinoma of the stomach (intestinal type) with widespread infiltration of the perigastric soft tissue, circumscribed penetration of the overlying serosa and thirty-nine regional lymph node metastases. Partly invasive and partly with lymphatic spread of the tumor into the aboral resection margin. Carcinoma-free oral resection margin. Tumor-free omentum.

Tumor stage: pT3 pN3 (39/40) pMX; ■

Source: NCI Genomic Data Commons file c8ccb26f-c8f5-4d45-898b-e2eefc8bd8a3 (TCGA-CG-4469.9E56C8B9-E8FD-4E48-A5DF-12CBB32B07D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).